Somatic mutation profile of tumor specimen TCGA-DC-4745-01A (aliquot TCGA-DC-4745-01A-01D-1733-10) from TCGA case TCGA-DC-4745, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 49.2 years (17,958 days).
Specimen TCGA-DC-4745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9238709d-5675-4dbd-935d-3031150f4ccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-4745-10A (Blood Derived Normal), aliquot TCGA-DC-4745-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/241ee202-9ff8-48dc-aab0-12ab306b6a4c

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Intron 2, Nonsense Mutation 2, Splice Site 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1007A>T p.K336I | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV101257019; called by muse, mutect2, varscan2
- AKAP12 | c.1823C>A p.T608N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99482435; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 37/45 reads (82%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- APOBR | c.2382T>A p.H794Q (on ENST00000431282; = p.H803Q on NM_018690.4) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100112259; called by muse, mutect2, varscan2
- ARFGAP2 | c.810-1G>A p.X270_splice | Splice Site (SNP) | VAF 79/195 reads (41%) | catalogued as COSV100125405; called by muse, mutect2, varscan2
- ASH1L | c.4243C>T p.P1415S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV100853120; called by muse, mutect2, varscan2
- ATP2A1 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs760340608, COSV100706823; called by muse, mutect2, varscan2
- AUTS2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV61388252; called by muse, mutect2, varscan2
- BASP1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs767831759, COSV100493552; called by muse, mutect2
- BAZ1B | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100289589; called by muse, mutect2, varscan2
- BCL9 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553204447, COSV99324507, COSV99324562; called by muse, mutect2, varscan2
- BHLHE41 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV54378338; called by muse, varscan2
- CCDC88A | c.4357G>A p.G1453S | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV99709817; called by muse, mutect2, varscan2
- COL12A1 | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs757917876, COSV59410225; called by muse, mutect2, varscan2
- COLQ | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs774271810, COSV67525355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL7 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1301329334, COSV54815794; called by muse, mutect2, varscan2
- DMD | c.11040G>T p.M3680I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as COSV58896766; called by muse, mutect2, varscan2
- DMRT3 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV99505657; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs1420189684, COSV56181614; called by muse, mutect2, varscan2
- FAM155B | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52936793, COSV99368152; called by muse, mutect2, varscan2
- FOXC2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100234106; called by muse, mutect2, varscan2
- GP2 | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100221266; called by muse, mutect2, varscan2
- GPR83 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99703562; called by muse, mutect2, varscan2
- IGSF10 | c.6190G>A p.G2064S | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768260632, COSV99176665; called by muse, mutect2, varscan2
- KDELR3 | c.6C>A p.N2K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99318065; called by muse, mutect2, varscan2
- KLHL2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56979260; called by muse, mutect2
- LAMB2 | c.3989A>T p.Y1330F | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV100025839; called by muse, mutect2, varscan2
- MEX3D | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV101183462; called by muse, mutect2, varscan2
- NLGN2 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs1366298154, COSV57209659; called by muse, mutect2, varscan2
- NYAP1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1336786473, COSV55718200; called by muse, mutect2, varscan2
- OR2M4 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV60708720; called by muse, mutect2, varscan2
- P3H3 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV99300875; called by muse, mutect2, varscan2
- PAGE3 | c.11A>C p.H4P | Missense Mutation (SNP) | VAF 123/215 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100891970; called by muse, mutect2, varscan2
- PAH | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs547566250, COSV100187645; called by muse, mutect2, varscan2
- PLEKHG4B | c.1580C>T p.T527M (on ENST00000283426; = p.T883M on NM_052909.5) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs138857981; called by muse, mutect2, varscan2
- POLR2H | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99658234; called by muse, mutect2, varscan2
- PTPRT | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV100625375, COSV61999164; called by muse, mutect2, varscan2
- RAB10 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53089230; called by muse, mutect2
- RAI2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs140631545, COSV58963272; called by muse, mutect2, varscan2
- RUBCNL | c.1828A>C p.T610P | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV59786329; called by muse, mutect2, varscan2
- SALL1 | c.1246T>G p.L416V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV99171568; called by muse, mutect2, varscan2
- SCN3A | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99329107; called by muse, mutect2
- SLC16A7 | c.83T>G p.I28S | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53892771; called by muse, mutect2, varscan2
- SLC32A1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV54145954; called by muse, mutect2, varscan2
- SLC35F6 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs760556570, COSV100733597; called by muse, mutect2, varscan2
- SNRPN | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100577893; called by muse, mutect2
- SRPK3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1557068204, COSV99472948; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs28689626; called by muse, mutect2, varscan2
- TRMU | c.873+1G>A p.X291_splice | Splice Site (SNP) | VAF 16/131 reads (12%) | catalogued as COSV99324444; called by muse, mutect2, varscan2
- TTC27 | c.2489C>T p.T830I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100512673; called by muse, mutect2, varscan2
- WDR74 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99586731; called by muse, mutect2, varscan2
- ZNF333 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV99468819; called by muse, mutect2
- ZPBP | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99249079; called by muse, mutect2, varscan2
- RBM38 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT4 | c.315del p.T108Pfs*20 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- CALD1 | c.1653C>T p.F551= (on ENST00000361675 / NM_033138.4; = p.F296= on NM_004342.7) | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs757030162, COSV62645894; called by muse, mutect2, varscan2
- CBARP | c.906C>T p.S302= (on ENST00000382477; = p.S282= on NM_152769.3) | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs369946345; called by muse, mutect2, varscan2
- DVL1 | c.1332C>T p.A444= (on ENST00000378888 / NM_001330311.2; = p.A419= on NM_004421.3) | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs750379091, COSV59562910; called by muse, mutect2, varscan2
- EDA | c.84C>T p.G28= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV58876104; called by muse, varscan2
- FSD1 | c.873C>T p.D291= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs376149637; called by muse, mutect2, varscan2
- GLT6D1 | c.657G>A p.P219= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs201383603, COSV65627181; called by muse, mutect2, varscan2
- HCFC1 | c.753G>A p.A251= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs1557117195, COSV60071151; called by muse, mutect2, varscan2
- HNRNPR | c.1230G>A p.K410= | Silent (SNP) | VAF 16/163 reads (10%) | catalogued as COSV100164325; called by muse, mutect2, varscan2
- IVL | c.141G>T p.V47= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100908105, COSV64216782; called by muse, mutect2, varscan2
- KCNH5 | c.2361C>T p.N787= | Silent (SNP) | VAF 147/385 reads (38%) | catalogued as rs778860669, COSV59755950; called by muse, mutect2, varscan2
- MUC16 | c.12057C>T p.D4019= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as rs778816991, COSV67489689; called by muse, mutect2, varscan2
- OTOF | c.5694C>T p.N1898= (on ENST00000272371 / NM_194248.3; = p.N1131= on NM_004802.4) | Silent (SNP) | VAF 57/166 reads (34%) | catalogued as rs1318486079, COSV55506552; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKIG | c.66G>A p.A22= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs761274365, COSV100596074; called by mutect2, varscan2
- PLA2G4E | c.468C>T p.D156= | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as COSV68149211; called by muse, mutect2
- POLR2A | c.3456G>A p.E1152= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1233093868; called by muse, mutect2, varscan2
- PRR12 | c.1953G>A p.P651= (on ENST00000615927; = p.P1472= on NM_020719.3) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1433937246, COSV101330565; called by muse, mutect2, varscan2
- PYGB | c.1833G>A p.A611= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as rs752184187, COSV53818211; called by muse, mutect2, varscan2
- AC244258.1 | n.927C>T | RNA (SNP) | VAF 90/187 reads (48%) | called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3936G>A | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs751662808, COSV62013419; called by muse, mutect2, varscan2
- JMJD1C | c.333+7272C>G | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1033617034, COSV101232201; called by muse, varscan2
